Gene-level copy-number profile of tumor specimen TCGA-AB-2860-03A from TCGA case TCGA-AB-2860, project TCGA-LAML (Acute Myeloid Leukemia). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute megakaryoblastic leukaemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 60.3 years (22,035 days).
Specimen TCGA-AB-2860-03A: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LAML.3ade6248-c5d9-4252-bef6-0eccedca2ad6.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AB-2860-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/02fc1b57-6118-48b5-9be6-a435cada6e4f

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 8,181; copy number 2: 49,929; copy number 3: 1,558; copy number 4: 133; copy number 5: 8; copy number 6: 10.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-AB-2860-03A-01D-0756-21): tumor purity 0.61, ploidy 1.9, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 18 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:88,051,944–88,467,594, 8 genes, copy number 5: CGGBP1, AC119733.1, ZNF654, CBX5P1, C3orf38, ABCF2P1, CSNKA2IP, Y_RNA.
- chr21:38,155,549–38,747,460, 10 genes, copy number 6: KCNJ15, AP001425.1, DSCR10, AP001434.1, SPATA20P1, LINC01423, ERG, SNRPGP13, AP001037.1, LINC00114.

Autosomal genes at a single copy (total copy number 1): 8,180. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
